Somatic mutation profile of tumor specimen TCGA-A4-8098-01A (aliquot TCGA-A4-8098-01A-11D-2396-08) from TCGA case TCGA-A4-8098, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 73.1 years (26,685 days).
Specimen TCGA-A4-8098-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 21b0a5de-d346-4eaa-ad62-c994334661f6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A4-8098-10A (Blood Derived Normal), aliquot TCGA-A4-8098-10A-01D-2396-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/779d8814-9695-43ad-80fc-807bf460d01a

The open-access MAF lists 87 somatic variants for this specimen: 69 protein-altering or splice-affecting, 18 silent.
By variant classification: Missense Mutation 51, Silent 18, Frame Shift Del 7, Frame Shift Ins 7, Nonsense Mutation 1, In Frame Ins 1, Splice Site 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACAA1 | c.667A>C p.I223L | Missense Mutation (SNP) | VAF 48/115 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as COSV57170003; called by muse, mutect2, varscan2
- AKAP3 | c.638A>C p.K213T | Missense Mutation (SNP) | VAF 115/192 reads (60%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.874); catalogued as COSV57413674; called by muse, mutect2, varscan2
- ANK2 | c.2655T>A p.N885K | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.05); PolyPhen benign (0.228); catalogued as COSV52145464; called by muse, mutect2, varscan2
- AP1G2 | c.1233-1G>A p.X411_splice | Splice Site (SNP) | VAF 41/61 reads (67%) | catalogued as COSV55337310; called by muse, mutect2, varscan2
- ARHGAP32 | c.4172G>A p.R1391Q (on ENST00000310343 / NM_001378025.1; = p.R1042Q on NM_014715.4) | Missense Mutation (SNP) | VAF 25/57 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); catalogued as rs530219324, COSV59843171; called by muse, mutect2, varscan2
- ARL6IP1 | c.170T>C p.L57P | Missense Mutation (SNP) | VAF 61/157 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as COSV58614016; called by muse, mutect2, varscan2
- CAPN7 | c.2161A>G p.I721V | Missense Mutation (SNP) | VAF 42/102 reads (41%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as COSV53776723; called by muse, mutect2, varscan2
- CD109 | c.82T>C p.F28L | Missense Mutation (SNP) | VAF 47/112 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV54645220; called by muse, mutect2, varscan2
- CHD1 | c.4490A>G p.Y1497C | Missense Mutation (SNP) | VAF 40/65 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749012080, COSV52336784; called by muse, mutect2, varscan2
- CKAP5 | c.2161T>C p.S721P | Missense Mutation (SNP) | VAF 3/44 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as COSV56363992; called by muse, mutect2
- CNNM4 | c.1391A>G p.E464G | Missense Mutation (SNP) | VAF 30/76 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1226167874, COSV65660215; called by muse, mutect2, varscan2
- CNTRL | c.2278T>G p.F760V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT tolerated (0.08); PolyPhen benign (0.024); catalogued as COSV53043129; called by muse, mutect2, varscan2
- CPB2 | c.210T>G p.F70L | Missense Mutation (SNP) | VAF 73/161 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.447); catalogued as COSV51672292; called by muse, mutect2, varscan2
- DNAH11 | c.11870G>T p.G3957V | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100176256, COSV60939287; called by muse, mutect2
- DNAH17 | c.5863G>C p.G1955R | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67749570, COSV67759337; called by muse, mutect2, varscan2
- DNM1 | c.1140T>A p.D380E | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.994); catalogued as COSV57848832; called by muse, mutect2, varscan2
- DRD5 | c.544A>T p.R182W | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV58576693, COSV58579516; called by muse, mutect2, varscan2
- EPPK1 | c.4895G>C p.G1632A | Missense Mutation (SNP) | VAF 39/117 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.78); catalogued as COSV73260795, COSV73261524; called by muse, mutect2, varscan2
- GPNMB | c.1126C>A p.H376N (on ENST00000381990 / NM_001005340.2; = p.H364N on NM_002510.3) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.345); catalogued as COSV51696834; called by muse, varscan2
- GSTP1 | c.224G>A p.R75H | Missense Mutation (SNP) | VAF 55/117 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.132); catalogued as rs771256487, COSV66992234; called by muse, mutect2, varscan2
- IMMP1L | c.176A>G p.H59R | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (0.75); PolyPhen benign (0.006); catalogued as COSV53442705; called by muse, mutect2, varscan2
- ITGA10 | c.968G>A p.R323K | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as COSV65195985; called by muse, mutect2, varscan2
- JUNB | c.202T>C p.Y68H | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.53); PolyPhen benign (0.006); catalogued as COSV56877274; called by muse, mutect2, varscan2
- LRRC1 | c.158A>T p.E53V | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.383); catalogued as COSV63823012; called by muse, mutect2, varscan2
- LRRC46 | c.687G>A p.M229I | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV51634871; called by muse, mutect2, varscan2
- LRRK1 | c.762A>G p.T254= | Splice Region (SNP) | VAF 29/62 reads (47%) | catalogued as COSV52601681; called by muse, mutect2, varscan2
- LSM14A | c.1211G>T p.R404L | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.614); catalogued as COSV70884665; called by muse, mutect2, varscan2
- MACROH2A2 | c.865C>A p.Q289K | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.233); catalogued as COSV57158547; called by muse, mutect2, varscan2
- MARCHF6 | c.1847G>A p.G616E | Missense Mutation (SNP) | VAF 44/149 reads (30%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.795); catalogued as rs1338277439, COSV56878690; called by muse, mutect2, varscan2
- MYH11 | c.623C>A p.T208K | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as COSV55542750; called by muse, mutect2, varscan2
- NELL1 | c.2347A>T p.M783L | Missense Mutation (SNP) | VAF 68/197 reads (35%) | SIFT tolerated (0.12); PolyPhen benign (0.077); catalogued as COSV100120640, COSV54238549; called by muse, mutect2, varscan2
- NRAP | c.3364G>C p.A1122P (on ENST00000359988 / NM_001322945.2; = p.A1087P on NM_006175.4) | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63488436, COSV63489677; called by muse, mutect2, varscan2
- PCDHGA3 | c.610A>T p.K204* | Nonsense Mutation (SNP) | VAF 36/126 reads (29%) | catalogued as COSV53897841; called by muse, mutect2, varscan2
- PEAR1 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs1228562041, COSV52770724; called by muse, mutect2, varscan2
- PHIP | c.1444C>T p.L482F | Missense Mutation (SNP) | VAF 11/75 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV51501360; called by muse, mutect2, varscan2
- PILRA | c.175T>G p.W59G | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); catalogued as COSV52199163; called by muse, mutect2, varscan2
- PLXNB3 | c.2485G>C p.E829Q | Missense Mutation (SNP) | VAF 11/11 reads (100%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as rs375202688, COSV62795417; called by muse, mutect2, varscan2
- POLR2A | c.178C>G p.P60A | Missense Mutation (SNP) | VAF 34/96 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV59489152; called by muse, mutect2, varscan2
- PRR5L | c.592C>T p.H198Y | Missense Mutation (SNP) | VAF 63/149 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61120074; called by muse, mutect2, varscan2
- PTPRZ1 | c.1918G>C p.E640Q | Missense Mutation (SNP) | VAF 41/97 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.782); catalogued as COSV66430139; called by muse, mutect2, varscan2
- RUVBL2 | c.328T>C p.S110P | Missense Mutation (SNP) | VAF 39/110 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55484199; called by muse, mutect2, varscan2
- SEPHS2 | c.350T>A p.I117N | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as COSV72100704, COSV72100708; called by muse, mutect2
- SETD2 | c.5304G>T p.K1768N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV57429873; called by muse, mutect2, varscan2
- SIPA1L3 | c.497T>C p.L166P | Missense Mutation (SNP) | VAF 48/117 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55908673; called by muse, mutect2, varscan2
- SLC18A3 | c.835G>C p.G279R | Missense Mutation (SNP) | VAF 30/123 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60320049; called by muse, mutect2, varscan2
- SLC2A4 | c.1309G>C p.G437R | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.579); catalogued as COSV50300371; called by muse, mutect2, varscan2
- SMG1 | c.2336C>T p.A779V | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT tolerated (0.75); PolyPhen benign (0.091); catalogued as rs781022848, COSV67169478; called by muse, mutect2, varscan2
- TET1 | c.5702T>G p.I1901S | Missense Mutation (SNP) | VAF 84/152 reads (55%) | SIFT deleterious (0.01); PolyPhen benign (0.326); catalogued as COSV65381966; called by muse, mutect2, varscan2
- TGM4 | c.61G>T p.A21S | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0.24); catalogued as COSV56092711; called by muse, mutect2, varscan2
- TMEM175 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 32/63 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.026); catalogued as COSV53277365; called by muse, mutect2, varscan2
- TRPC3 | c.2136T>G p.D712E (on ENST00000379645 / NM_001366479.2; = p.D639E on NM_003305.2) | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.119); catalogued as COSV53371754; called by muse, mutect2, varscan2
- TXNL4B | c.287C>A p.S96Y | Missense Mutation (SNP) | VAF 25/59 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV51702692; called by muse, mutect2, varscan2
- UBA1 | c.1939T>G p.W647G | Missense Mutation (SNP) | VAF 25/31 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60111183; called by muse, mutect2, varscan2
- ADAM29 | c.2161dup p.I721Nfs*7 | Frame Shift Ins (INS) | VAF 40/75 reads (53%) | called by mutect2, pindel, varscan2
- ATP1B1 | c.868_887del p.R290Cfs*4 | Frame Shift Del (DEL) | VAF 24/81 reads (30%) | called by mutect2, pindel, varscan2
- CENPH | c.672del p.V225Sfs*22 | Frame Shift Del (DEL) | VAF 27/60 reads (45%) | called by mutect2, pindel, varscan2
- GALNT5 | c.1105dup p.S369Ffs*7 | Frame Shift Ins (INS) | VAF 44/143 reads (31%) | called by mutect2, pindel, varscan2
- HEPHL1 | c.1543_1544dup p.F516Pfs*12 | Frame Shift Ins (INS) | VAF 5/26 reads (19%) | called by mutect2, pindel, varscan2
- LGR4 | c.366_367insCTT p.S122_E123insL | In Frame Ins (INS) | VAF 23/77 reads (30%) | called by mutect2, pindel, varscan2
- MSH3 | c.3113_3116dup p.S1039Rfs*14 | Frame Shift Ins (INS) | VAF 37/156 reads (24%) | called by mutect2, pindel, varscan2
- NCOA2 | c.3894_3897dup p.P1300Vfs*14 | Frame Shift Ins (INS) | VAF 10/48 reads (21%) | called by mutect2, pindel, varscan2
- OTOF | c.3910dup p.E1304Gfs*34 (on ENST00000272371 / NM_194248.3; = p.E537Gfs*34 on NM_004802.4) | Frame Shift Ins (INS) | VAF 26/86 reads (30%) | called by mutect2, pindel
- SLC26A8 | c.2075del p.N692Tfs*48 | Frame Shift Del (DEL) | VAF 41/116 reads (35%) | called by mutect2, pindel, varscan2
- STAG2 | c.2729_2732del p.I910Tfs*20 | Frame Shift Del (DEL) | VAF 41/53 reads (77%) | called by mutect2, pindel, varscan2
- TAF15 | c.1711G>T p.G571C (on ENST00000605844 / NM_139215.3; = p.G568C on NM_003487.4) | Missense Mutation (SNP) | VAF 52/158 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- TASOR2 | c.4857del p.G1621Vfs*3 | Frame Shift Del (DEL) | VAF 24/124 reads (19%) | called by mutect2, pindel, varscan2
- TGIF2 | c.449dup p.L151Afs*12 | Frame Shift Ins (INS) | VAF 36/105 reads (34%) | called by mutect2, pindel, varscan2
- UEVLD | c.865del p.L289Cfs*11 | Frame Shift Del (DEL) | VAF 31/99 reads (31%) | called by mutect2, pindel, varscan2
- UFL1 | c.1465del p.H489Tfs*17 | Frame Shift Del (DEL) | VAF 12/36 reads (33%) | called by mutect2, pindel, varscan2
- AAMDC | c.177G>A p.E59= | Silent (SNP) | VAF 84/245 reads (34%) | catalogued as COSV59016214; called by muse, mutect2, varscan2
- ADAMTS13 | c.1821G>T p.G607= | Silent (SNP) | VAF 29/97 reads (30%) | catalogued as COSV63019910; called by muse, mutect2, varscan2
- C1orf112 | c.1605C>T p.S535= | Silent (SNP) | VAF 21/61 reads (34%) | catalogued as COSV53676558; called by muse, mutect2, varscan2
- EIF2AK2 | c.534C>T p.S178= | Silent (SNP) | VAF 29/66 reads (44%) | catalogued as rs769967437, COSV51794624; called by muse, mutect2, varscan2
- GFM2 | c.1704C>A p.I568= | Silent (SNP) | VAF 31/108 reads (29%) | catalogued as COSV57189603; called by muse, mutect2, varscan2
- MIS18BP1 | c.1131T>G p.L377= | Silent (SNP) | VAF 29/44 reads (66%) | catalogued as COSV60368995; called by muse, mutect2, varscan2
- MYL9 | c.459C>T p.N153= | Silent (SNP) | VAF 19/63 reads (30%) | catalogued as COSV54072074; called by muse, mutect2, varscan2
- PARP4 | c.2673A>G p.T891= | Silent (SNP) | VAF 96/269 reads (36%) | catalogued as rs1332651761, COSV67960374; called by muse, mutect2, varscan2
- PCF11 | c.1785A>G p.K595= | Silent (SNP) | VAF 49/115 reads (43%) | catalogued as COSV53527447; called by muse, mutect2, varscan2
- PCSK7 | c.1866C>T p.I622= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as COSV99638966; called by muse, mutect2, varscan2
- PNPLA6 | c.1881G>A p.A627= (on ENST00000414982 / NM_001166111.2; = p.A579= on NM_006702.5) | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as rs1313582251, COSV55373504; called by muse, mutect2, varscan2
- POC5 | c.1257C>G p.S419= (on ENST00000428202 / NM_001099271.2; = p.S394= on NM_152408.2) | Silent (SNP) | VAF 46/189 reads (24%) | catalogued as COSV66841495; called by muse, mutect2, varscan2
- PRSS53 | c.441G>A p.Q147= | Silent (SNP) | VAF 41/88 reads (47%) | catalogued as COSV54922602; called by muse, mutect2, varscan2
- SEMA6C | c.921G>A p.V307= | Silent (SNP) | VAF 46/155 reads (30%) | catalogued as rs754923536, COSV58999912; called by muse, mutect2, varscan2
- SLC22A7 | c.153G>A p.L51= | Silent (SNP) | VAF 34/86 reads (40%) | catalogued as rs1164677640, COSV65353352; called by muse, mutect2, varscan2
- STYXL2 | c.1761A>G p.T587= | Silent (SNP) | VAF 27/59 reads (46%) | catalogued as COSV54801950; called by muse, mutect2, varscan2
- TMEM131 | c.2991A>T p.A997= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as COSV51769957; called by muse, mutect2, varscan2
- TRIM8 | c.879G>A p.T293= | Silent (SNP) | VAF 8/88 reads (9%) | catalogued as COSV56659492; called by muse, mutect2
